Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAFC, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAFC-01A (Primary Tumor).

Department of Pathology

ICD-O-3

Seminoma NOS 9061/3
Site R Testis NOS C62.9
W 3/8/14

Direct dial
Mobile:
Internal postal address
E-mail
Date

Concerning

Summary pathology report

Right orchidectomy; seminoma; diameter 4 cm; tumor confined to testis in available slides; no angio-invasion; no invasion in rete testis.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 5c69d803-5e62-4eb2-b27f-db76c254492b (TCGA-2G-AAFC-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).